Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PF, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PF-01A (Primary Tumor).

[page 1 of 3]
CCF ICD O-3
Adenocarcinoma, tubular 8211/3
path Adenocarcinoma w/ mixed cell types
8253/3
Site: Body of stomach 06.2
7/3/7/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

5 - "Product of standardized gastrectomy", 4 - "Greater omentum" 3 - "Esophageal margin"

Adenocarcinoma:

Location: posterior wall of the body.

Histological pattern observed:

Tubular - Pw TSS, 100% tubular.

Microtubular

Solid

Histological grade:

III - poorly differentiated.

Lauren's classification: intestinal type

Measure of the greatest axis of the tumor: 6.5 cm

Ulceration: present

Involvement of:

Mucosa

Muscularis mucosae

Submucosa

Muscularis propria

Adjacent adipose tissue

Type of tumor invasion: spiculated

Inflammatory reaction: intense

Tumor implantation in perivisceral adipose tissue: not detected

Proximal and distal margins: absence of neoplastic involvement.

Neural infiltration: present

Lymphatic vascular invasion: present

Blood vascular invasion: present

Greater omentum: absence of neoplastic involvement.

Involved lymph nodes:

Capsular transposition: present

Conglomerated lymph nodes: present

Ratio of involved/dissected lymph nodes: 24/41

Discrimination of lymph nodes according to standardization,
(compromised/dissected):

F - Chain 1 - right paracardics: 0/2

G - Chain 2 - left paracardics: 0/0

H - Chain 3 - along the lesser curvature: 3/3

I - Chain 4sa - along the short gastric vessels: 0/1

[page 2 of 3]
J - Chain 4sb - along the left gastroepiploic vessels: 5/11
L - Chain 5 - suprapylorics: 0/1
M - Chain 6 - infrapylorics: 0/4
P - Chain 8p - along the posterior hepatic artery (posterior group): 0/3
Q - Chain 9 - around the celiac trunk: 12/12
S - Chain 11p - along the proximal splenic artery: 4/4

- 1 - "Spleen"

Absence of neoplastic involvement.

2 - "Gallbladder":

Absence of neoplastic involvement.

Pathological Staging: pT3 pN3b

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Tubular, Microtubular, Solid Adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Tubular (100%)	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case was reviewed based on top slide to be sent to BCR	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed of the above discrepancy in diagnoses.

Principal Investigator Signature

Date _____

Per TSS dx discrepancy form
States TCGA tumor to be adenocarcinoma,
tubular.
BCR

Metastatic History	☐	☒
Metastatic Synchronous Primary	☐	☒
Use is (circle)	☒	☐
Interviewer Initials	AAA	

Source: NCI Genomic Data Commons file 1b414cb6-7484-4d63-8ead-ae7be3c9781b (TCGA-VQ-A8PF.B8EC8A4E-1DBF-48B8-BEFB-6EBD03ABA122.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).